Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7Q9, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7Q9-01B (Primary Tumor).

[page 1 of 4]
Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Location:

Surgical Pathology (OrderID:)	Final Results
-------------------------------	---------------

Surgical Pathology

CASE NUMBER:
DIAGNOSIS:

Final

1. Portion of right adrenal gland, frozen section (1FS): Adrenal gland, no tumor seen.
2. Kidney, cyst wall, right, resection: Fibrous tissue, no tumor seen.
3. Kidney, tumor, right, resection:
- * Renal cell carcinoma chromophobe type with marked hemorrhage and areas of fibrosis.
- * See Note.
4. Kidney, right, radical nephrectomy:
- * Renal parenchyma with chronic interstitial nephritis and moderate atherosclerosis, no tumor seen.
- * Ureteral and vascular margins free of tumor.
- * Vessels with organizing thrombus.
- * See Note.
5. Lymph nodes, paracaval, resection: Adipose tissue, no lymph nodes or tumor identified.

ICD-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site @ Kidney NOS
64.9
J 9/24/13

NOTE:

SURGICAL PATHOLOGY CANCER CASE SUMMARY

Procedure: Radical nephrectomy
Specimen Laterality: Right
Tumor Size: 5.3 x 5.3 x 2 cm
Tumor Focality: Unifocal
Macroscopic Extent of Tumor: Tumor limited to kidney
Histologic Type: Chromophobe renal cell carcinoma
Sarcomatoid Features: Not identified
Histologic Grade (Fuhrman Nuclear Grade): Not applicable
Microscopic Tumor Extension: Tumor limited to kidney
Margins: Margins uninvolved by invasive carcinoma
Lymph-Vascular Invasion: Not identified

Pathologic Staging (pTNM)

Primary Tumor (pT): pT1b
Regional Lymph Nodes (pN): No nodes submitted or found
Distant Metastasis (pM): Not applicable

Pathologic Findings in Nonneoplastic Kidney: Chronic interstitial nephritis, atherosclerosis

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics

[page 2 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID: _____] Final Results

CLINICAL INFORMATION: Brief Clinical History: right renal tumor
Specimen Taken For Protocol:
01 - Yes Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: right renal tumor Post-Operative
Diagnosis:
right renal tumor Operative Findings: tumor invading into segmental
renal vein, enlarged retroperitoneal lymph nodes

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT, Portion -1fs
2. KIDNEY, RIGHT, Cyst Wall
3. KIDNEY, RIGHT, Tumor
4. KIDNEY, RIGHT
5. LYMPH NODES. Paracaval

INTRAOPERATIVE CONSULTATION:

1FS "Portion RT adrenal FS"

1FS DX: Benign adrenal cortex.

The frozen section was performed by _____ on _____

GROSS DESCRIPTION:

1. Received fresh from the OR labeled with the patient's name, medical record number, and date of birth, and further specified as "portion RT adrenal FS" is an irregularly-shaped red-tan soft tissue fragment measuring 1.7 x 1.2 x 0.7 cm, a portion of which is submitted for frozen section diagnosis as 1FS. The specimen is wrapped in lens paper, placed in a green cassette and transferred to formalin. The specimen received in Surgical Pathology matches the above description. Frozen section specimen is transferred to an orange cassette labeled 1FS for permanent processing. The additional small fragment of tissue is filtered into a biopsy bag and entirely submitted in a white cassette labeled _____ for permanent processing.

2. Received in formalin-filled container labeled with the patient's name, MRN, date of birth and "right kidney cyst wall" is a cauterized white to tan soft tissue fragment measuring 1.0 x 0.5 x 0.3 cm, entirely submitted in a white cassette labeled _____ for permanent processing.

3. Received in a container labeled with the patient's name, MRN, date

[page 3 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age: :
		Location:

Surgical Pathology [OrderID:]**Final Results**

of birth and further specified as "right kidney tumor" is a partially disrupted partial nephrectomy specimen measuring 5.3 x 5.3 x 2 cm and weighing 63.3 grams. Gross photographs are taken. It is well-circumscribed with a mottled red to brown hemorrhagic cut surface. Approximately 2 x 1.5 x 1 cm of tumor procured for the . The specimen is placed in formalin and submitted to Pathology for permanent processing. Procurement was performed . The specimen is received in Surgical Pathology and matches the above description. The specimen is further serially sectioned and representative sections of central and peripheral tumor are submitted in cassettes 3A-3F for permanent processing.

4. Received fresh in a container labeled with the patient's name, MRN, and further specified as "right kidney is an 842.8 g radical nephrectomy measuring overall 25 x 13 x 4 cm. Gross photographs are taken. The posterior and part of the anterolateral portion of the specimen are inked in black. Approximately 3 x 2 x 1 cm of normal kidney parenchyma is procured. The remainder of the specimen is placed in formalin and submitted to Pathology for permanent processing. The procurement was performed by . on . The specimen is received in Surgical Pathology and matches the above description. 6.3 cm of ureter is present. The kidney is opened revealing a 5 x 5 cm area, where partial nephrectomy was performed. The lower pole within potentially fat or a structure is a yellow-tan hemorrhagic nodule.

Summary of cassettes for permanent processing:

- 4A: Vascular and ureteral margins
- 4B: Upper pole parenchyma
- 4C: Representative section of vasculature from pelvis
- 4D: Representative section of the lower pole nodule
- 4E: Residual "tumor" in the nephrectomy cavity and
- 4G, 4H: Representative sections with central thrombi/hemorrhage from the posterior portion of the lower pole
- 4I: Fascia in closest contact with the mass
- 4J: Two additional representative sections from the lower pole
- 4K Two candidate lymph nodes from the renal pelvis
- 4L: Additional sections of ureteral margin

5. Received in a formalin-filled container labeled with the patient's name, MRN, date of birth, and further specified as "paracaval lymph node" is a 6.3 x 6.0 x 2.5 cm matted yellow fibroadipose tissue. The specimen is explored for lymph nodes. No candidate lymph nodes are identified. Segment of fibrovascular tissue is submitted in cassettes 5A-5E for permanent processing.

Gross Description dictated by on

No consultants

Accessioned:

Final Report Signed Out:

[page 4 of 4]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Location:

Surgical Pathology (OrderID:	Final Results
------------------------------	---------------

<Resident Signature>

M.D. PhD. CLINICAL RESIDENT

<Sign Out Dr. Signature>

MD, ATTENDING STAFF PATHOLOGIST

Date Report Signed:

Criteria	W 9/13/13	No

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 1516959c-f793-483e-b0a3-94ffd34c884e (TCGA-KM-A7Q9.D4B803C9-2284-4B0A-90E7-FF86D56B1501.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).